Surgical pathology report (de-identified scan), TCGA case TCGA-85-7699, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-7699-01A (Primary Tumor).

[page 1 of 2]
Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy
Tumor site: Lung
Tumor size: 3 x 2 x 2 cm
Histologic type: Squamous cell carcinoma
Histologic grade: Poorly differentiated
Tumor extent: Not specified
Other tumor nodules: Not specified
Lymph nodes: Not specified
Lymphatic invasion: Not specified
Venous invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

ID	Laterality	Date of procurement
	Left-upper	

Source: NCI Genomic Data Commons file 4d6c3581-6179-4d2c-8a49-1421e4fbe3bf (TCGA-85-7699.C95B2907-7C16-4F93-81FF-D1F3AADCD413.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).